Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A24H, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A24H-01A (Primary Tumor).

ICD-0-3
Carcinoma, infiltrating lobular, nos 8520/3
Site: breast, nos C50.9
lu 4/24/11

Final Diagnosis

Breast, right, excision: Invasive lobular carcinoma, Nottingham II (of III), forming a 2.8 x 2.6 x 2 cm mass (AJCCpt2). No lymphovascular involvement or carcinoma in situ component is identified. The surgical resection margins, after one re-excision are negative for tumor. The uninvolved breast tissue shows duct ectasia and stromal fibrosis.

Lymph node, right axilla, sentinel, excision: A single right sentinel lymph node is negative for tumor.

Lymph nodes, right axilla, excision: Multiple (3) right axillary lymph nodes are negative for tumor.

Staining for estrogen and progesterone receptors is positive.

Source: NCI Genomic Data Commons file 3740701d-07a1-4251-b072-43cf58cc4aa5 (TCGA-AR-A24H.C373F2EE-C601-4E17-8E2D-D9BC6AC0301A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).